Gene-level copy-number profile of tumor specimen TCGA-14-0871-01A from TCGA case TCGA-14-0871, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.0 years (27,387 days).
Specimen TCGA-14-0871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.213a8ca0-e32a-4878-b2ef-547910993836.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,872 have no estimate.
https://portal.gdc.cancer.gov/files/def83393-3ccf-4295-aa23-72cc980b13cc

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 96; copy number 2: 1,213; copy number 3: 4,381; copy number 4: 11,147; copy number 5: 16,255; copy number 6: 9,529; copy number 7: 12,125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0871-01A-01D-0384-01): tumor purity 0.93, ploidy 5.4, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:61,610,424–61,833,024, 5 genes (within-gene range 0–3): C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
